Somatic mutation profile of tumor specimen ALCH-B2MO-TTP1-A (aliquot ALCH-B2MO-TTP1-A-1-0-D-A777-36) from ALCHEMIST case ALCH-B2MO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,196 days).
Specimen ALCH-B2MO-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecf2cc7e-0492-4796-a315-011dccf27bb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2MO-NB1-A (Blood Derived Normal), aliquot ALCH-B2MO-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/733b62ce-a2c0-41da-a2e9-0c4f926c65db

The open-access MAF lists 815 somatic variants for this specimen: 568 protein-altering or splice-affecting, 143 silent, 104 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 488, Silent 143, Intron 47, Nonsense Mutation 45, RNA 26, 3'UTR 17, Splice Site 16, Splice Region 8, Frame Shift Del 6, 5'UTR 5, 5'Flank 5, 3'Flank 4.

Variants (750 of 815; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 83/549 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879253942, CD004355, CM971505, COSV52706540, COSV52732531, COSV53696163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3620G>T p.C1207F (on ENST00000404938 / NM_001163941.2; = p.C762F on NM_178559.6) | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347891707; called by muse, mutect2
- ABCC12 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV60915304, COSV60917912; called by muse, mutect2
- ABCC2 | c.4542G>T p.E1514D | Missense Mutation (SNP) | VAF 37/620 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV64984395; called by muse, mutect2
- ACTRT1 | c.189C>A p.Y63* | Nonsense Mutation (SNP) | VAF 8/133 reads (6%) | catalogued as COSV64419117, COSV64419691; called by muse, mutect2
- ADAMTS16 | c.964-1G>T p.X322_splice | Splice Site (SNP) | VAF 28/420 reads (7%) | catalogued as COSV99942021; called by muse, mutect2
- ADCY10 | c.3859C>A p.L1287M | Missense Mutation (SNP) | VAF 56/710 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs773492387; called by muse, mutect2
- ADCY2 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57868798, COSV57902234; called by muse, mutect2
- AGAP2 | c.1228-2A>T p.X410_splice (on ENST00000547588 / NM_001122772.2; = p.X74_splice on NM_014770.4) | Splice Site (SNP) | VAF 52/243 reads (21%) | catalogued as COSV57733101; called by muse, mutect2, varscan2
- AGXT2 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 44/576 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51483937; called by muse, mutect2
- AHCY | c.1051A>G p.M351V | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.088); catalogued as rs1443450433; called by muse, mutect2
- AKAP12 | c.2882G>A p.R961Q | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1160947598, COSV99483065; called by muse, mutect2
- ALPG | c.543C>A p.H181Q | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99779271; called by muse, mutect2
- ANKRD26 | c.980C>T p.S327L | Missense Mutation (SNP) | VAF 35/490 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs1046050910, COSV65793796; called by muse, mutect2
- ANXA8 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 15/337 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1284603752; called by muse, mutect2
- ASB12 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as rs762637977; called by mutect2, varscan2
- ASTN2 | c.1194G>T p.K398N (on ENST00000313400 / NM_001365069.1; = p.K347N on NM_014010.5) | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as COSV57774258; called by muse, mutect2
- ATF7IP | c.1930del p.X644_splice | Splice Site (DEL) | VAF 26/160 reads (16%) | catalogued as COSV99661495; called by mutect2, varscan2
- ATP2B3 | c.2384G>C p.G795A | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54844983; called by muse, mutect2
- ATP6V1H | c.644G>T p.R215L | Missense Mutation (SNP) | VAF 27/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146380497; called by muse, mutect2
- BRINP2 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.249); catalogued as rs146557924; called by muse, mutect2
- BRINP3 | c.1781C>A p.P594Q | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100819606; called by muse, mutect2
- C1orf68 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 46/698 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64224931; called by muse, mutect2
- CCT3 | c.177G>C p.M59I | Missense Mutation (SNP) | VAF 42/572 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.023); catalogued as COSV55291778; called by muse, mutect2
- CDH10 | c.1657G>T p.G553* | Nonsense Mutation (SNP) | VAF 20/315 reads (6%) | catalogued as rs770340870, COSV52584569; called by muse, mutect2
- CDH18 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs375530344, COSV56975305; called by muse, mutect2
- CDK20 | c.563+5G>A | Splice Region (SNP) | VAF 14/110 reads (13%) | catalogued as rs759042973; called by mutect2, varscan2
- CELSR1 | c.5570A>G p.N1857S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as rs1376468034; called by muse, mutect2
- CEP120 | c.2104-1G>T p.X702_splice | Splice Site (SNP) | VAF 12/112 reads (11%) | catalogued as rs1394632495; called by muse, mutect2, varscan2
- CLEC14A | c.716C>A p.S239* | Nonsense Mutation (SNP) | VAF 18/231 reads (8%) | catalogued as rs570149280; called by muse, mutect2
- CNTNAP2 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1563086528, COSV62212945; called by muse, mutect2
- COL18A1 | c.3134G>T p.G1045V (on ENST00000359759 / NM_130444.3; = p.G810V on NM_030582.4) | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs747357360; called by muse, mutect2, varscan2
- COL21A1 | c.1823G>T p.G608V | Missense Mutation (SNP) | VAF 46/398 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55161063; called by muse, varscan2
- COL3A1 | c.2414del p.P805Lfs*431 | Frame Shift Del (DEL) | VAF 44/461 reads (10%) | catalogued as COSV58582814; called by mutect2, pindel, varscan2
- CPED1 | c.2542C>A p.L848I | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1278152351, COSV60002748, COSV60004550; called by muse, mutect2
- CTC1 | c.2420G>T p.W807L | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59853144; called by muse, mutect2, varscan2
- CTLA4 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 16/411 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.12); catalogued as COSV99865367; called by muse, mutect2
- CYP2D7 | c.373G>A p.G125R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1424037221; called by muse, mutect2, varscan2
- DCHS1 | c.9707G>A p.R3236H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1418163020, COSV54996730; called by muse, mutect2, varscan2
- DDX23 | c.1351G>T p.V451F | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV57286180; called by muse, mutect2, varscan2
- DDX60 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67095994; called by mutect2, varscan2
- DIDO1 | c.2472G>C p.K824N | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV56617692; called by muse, mutect2
- DMD | c.6821G>T p.G2274V | Missense Mutation (SNP) | VAF 44/607 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.068); catalogued as COSV58939304; called by muse, mutect2
- DOCK4 | c.5053G>T p.A1685S | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.339); catalogued as rs1364848530; called by muse, mutect2
- DPP3 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 26/416 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57856443; called by muse, mutect2
- DSG1 | c.2286C>A p.S762R | Missense Mutation (SNP) | VAF 52/804 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as rs1288428132; called by muse, mutect2
- DUOX1 | c.3781G>T p.G1261W | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as COSV58477787; called by muse, mutect2, varscan2
- EDA2R | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as rs1207666953; called by muse, mutect2
- EDN3 | c.300C>A p.F100L | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV61110294; called by muse, mutect2
- EEF1AKMT4-ECE2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs763136855, COSV62567064; called by muse, mutect2, varscan2
- ELFN1 | c.1838C>A p.A613E | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.239); catalogued as COSV70034255; called by muse, mutect2
- ELN | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 24/287 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1287098263; called by muse, mutect2
- ENOX1 | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54921649; called by muse, mutect2, varscan2
- EPS8L3 | c.1538G>T p.G513V (on ENST00000361965 / NM_133181.4; = p.G483V on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/364 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as rs983041666, COSV62610127; called by muse, mutect2
- ERO1A | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 27/392 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV67471652; called by muse, mutect2
- ESCO1 | c.674A>G p.E225G | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs757899677; called by muse, mutect2, varscan2
- ESRRB | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 27/280 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs1266043578, COSV55059292; called by muse, mutect2, varscan2
- F13A1 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 26/514 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194623661; called by muse, mutect2
- FCGBP | c.10175G>T p.G3392V | Missense Mutation (SNP) | VAF 78/501 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.944); catalogued as rs751337039; called by muse, mutect2, varscan2
- FLG | c.7636C>A p.H2546N | Missense Mutation (SNP) | VAF 25/402 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV64245877; called by muse, mutect2
- FLI1 | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 41/647 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs939529769; called by muse, mutect2
- FLNA | c.2414G>T p.S805I | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61045791; called by muse, mutect2
- FLRT2 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs750040176, COSV58146461; called by mutect2, varscan2
- FRMPD4 | c.3838C>A p.P1280T | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as COSV66224048; called by muse, mutect2
- GABRB1 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV54991072; called by muse, mutect2
- GABRG2 | c.874G>T p.V292L (on ENST00000361925 / NM_001375343.1; = p.V252L on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/465 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.077); catalogued as COSV62715619; called by muse, mutect2
- GOT1 | c.283G>C p.A95P | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV65147549; called by muse, mutect2
- GPC3 | c.169G>C p.V57L | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV63658945; called by muse, mutect2
- GPR119 | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99358571; called by muse, mutect2
- GPRASP2 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs759856219, COSV59991852; called by muse, mutect2, varscan2
- GYPC | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52148033, COSV52148412; called by muse, mutect2
- HDAC9 | c.738G>T p.K246N | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1057224879, COSV101287324; called by muse, mutect2
- HDX | c.150G>T p.T50= | Splice Region (SNP) | VAF 4/35 reads (11%) | catalogued as rs769377996; called by mutect2, varscan2
- HECTD4 | c.7458C>A p.P2486= | Splice Region (SNP) | VAF 40/215 reads (19%) | catalogued as COSV101107466; called by muse, mutect2, varscan2
- HECW1 | c.3146C>G p.P1049R | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67839608; called by muse, mutect2
- HIVEP2 | c.3376G>C p.V1126L | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs769570765; called by muse, mutect2
- HOMER2 | c.782G>T p.R261L (on ENST00000304231 / NM_199330.3; = p.R250L on NM_004839.4) | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV58484730; called by mutect2, varscan2
- HRNR | c.2222A>T p.Q741L | Missense Mutation (SNP) | VAF 13/393 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV64259155; called by muse, mutect2
- IGFL3 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1237755541, COSV58242873; called by muse, mutect2
- INSC | c.1612G>T p.A538S | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761946467; called by muse, mutect2, varscan2
- ISL1 | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 29/415 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as COSV100045137; called by muse, mutect2
- ITGA5 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99516860; called by muse, mutect2, varscan2
- KAZN | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV63210343; called by muse, mutect2
- KCNH5 | c.2584G>C p.D862H | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as rs780323870, COSV100525701; called by muse, mutect2
- KCNK12 | c.871A>G p.I291V | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as rs780808345; called by muse, mutect2
- KNTC1 | c.1981G>T p.E661* | Nonsense Mutation (SNP) | VAF 32/208 reads (15%) | catalogued as COSV61078989; called by muse, varscan2
- KRT28 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV60686449; called by muse, mutect2
- KRTAP17-1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 11/189 reads (6%) | PolyPhen probably damaging (0.999); catalogued as rs1487239373; called by muse, mutect2
- LAMB1 | c.4930G>A p.A1644T | Missense Mutation (SNP) | VAF 31/312 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.234); catalogued as rs1473749277, COSV55966817; called by muse, mutect2, varscan2
- LAMC3 | c.2353C>A p.R785S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs144930767, COSV63091766; called by muse, mutect2, varscan2
- LOXHD1 | c.3852C>A p.D1284E | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.329); catalogued as rs487706; called by muse, mutect2, varscan2
- LPA | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 28/512 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100305902; called by muse, mutect2
- LPAR4 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as COSV101425067; called by muse, mutect2
- LRP1B | c.12172G>T p.D4058Y | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67206505, COSV67283723; called by muse, mutect2
- LTBP1 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs985929702; called by muse, mutect2
- MAG | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as rs1245393323; called by muse, mutect2
- MAGEC1 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as rs571922643, COSV53567359; called by muse, mutect2
- MAGEC3 | c.1488G>T p.M496I | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV53577334; called by muse, mutect2, varscan2
- MGAT4A | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs905752978, COSV53850821; called by muse, mutect2
- MKI67 | c.6046G>T p.G2016C | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.389); catalogued as COSV64073818; called by muse, mutect2, varscan2
- MORC1 | c.2671G>T p.D891Y | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99226481; called by muse, mutect2, varscan2
- MUC4 | c.2975C>G p.P992R | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV100642126; called by muse, varscan2
- NBN | c.1969A>T p.T657S | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV55377342; called by muse, mutect2
- NCALD | c.528C>A p.D176E | Missense Mutation (SNP) | VAF 26/313 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs146483143; called by muse, mutect2
- NETO1 | c.589A>G p.S197G | Missense Mutation (SNP) | VAF 54/588 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774173210; called by muse, mutect2
- NISCH | c.3979G>T p.D1327Y | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58738275; called by muse, mutect2, varscan2
- NRXN3 | c.1444G>T p.G482C (on ENST00000335750 / NM_001330195.2; = p.G109C on NM_004796.6) | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59819099; called by muse, mutect2
- NSUN3 | c.504G>C p.L168F | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV58936880; called by muse, mutect2
- OBSCN | c.19915C>A p.P6639T | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769357971; called by muse, mutect2, varscan2
- OR10K1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs188612034, COSV56870795, COSV56872483; called by muse, mutect2
- OR10W1 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV67720716; called by muse, mutect2
- OR14C36 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 11/156 reads (7%) | catalogued as COSV58600960, COSV58601720; called by muse, mutect2
- OR2W3 | c.407T>A p.M136K | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV64458344; called by muse, mutect2
- OR4C16 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV58942770; called by muse, mutect2
- OR6C2 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.144); catalogued as COSV100498733; called by muse, mutect2, varscan2
- OR6N2 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.685); catalogued as COSV59410889; called by muse, mutect2
- OR6P1 | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1304649702, COSV58108341; called by muse, mutect2
- PASK | c.934A>T p.S312C | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52150158; called by muse, mutect2, varscan2
- PAX7 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV64750345; called by muse, mutect2
- PCDH15 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 26/490 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1379900720; called by muse, mutect2
- PCDHA8 | c.1960C>G p.H654D | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV65322989; called by muse, mutect2
- PCF11 | c.2396G>T p.G799V | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs1200361714; called by muse, mutect2
- PHF8 | c.1936G>T p.E646* (on ENST00000357988 / NM_001184896.1; = p.E610* on NM_015107.3) | Nonsense Mutation (SNP) | VAF 14/208 reads (7%) | catalogued as COSV57682260; called by muse, mutect2
- PIEZO2 | c.5704G>T p.V1902L | Missense Mutation (SNP) | VAF 18/191 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV53295425; called by muse, mutect2
- PLCG2 | c.221G>T p.R74L | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV63867883; called by muse, mutect2
- POM121L12 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV68692350; called by muse, mutect2
- PRR23C | c.670C>G p.P224A | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as rs1372208318; called by muse, mutect2
- PRRX2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs1370493903, COSV65241592, COSV65242787; called by muse, mutect2, varscan2
- PXDNL | c.4141G>T p.E1381* | Nonsense Mutation (SNP) | VAF 20/214 reads (9%) | catalogued as COSV62483418; called by muse, mutect2
- PXYLP1 | c.768G>T p.K256N | Missense Mutation (SNP) | VAF 33/359 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.096); catalogued as COSV53890290; called by muse, mutect2
- RBMXL2 | c.859G>T p.G287* | Nonsense Mutation (SNP) | VAF 11/124 reads (9%) | catalogued as COSV60980147; called by muse, mutect2
- REG1B | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1290021844; called by muse, mutect2
- RGS7 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 17/382 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as COSV100466835, COSV100469032; called by muse, mutect2
- RIMS2 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 33/377 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV68113166; called by muse, mutect2
- SEC23A | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV100305548; called by muse, mutect2
- SEMA3C | c.1355-1G>T p.X452_splice | Splice Site (SNP) | VAF 28/188 reads (15%) | catalogued as COSV54849764; called by muse, mutect2, varscan2
- SI | c.2407G>T p.D803Y | Missense Mutation (SNP) | VAF 31/371 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV52298909; called by muse, mutect2
- SLC17A6 | c.921del p.F307Lfs*9 | Frame Shift Del (DEL) | VAF 30/288 reads (10%) | catalogued as rs752826797; called by pindel, varscan2
- SLIT3 | c.3596G>C p.G1199A | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV100268592, COSV60609133; called by muse, mutect2
- SMARCC1 | c.918+1G>T p.X306_splice | Splice Site (SNP) | VAF 14/170 reads (8%) | catalogued as COSV99592382; called by muse, mutect2
- SNTG1 | c.605G>C p.R202P | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52439975; called by muse, mutect2
- SOBP | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs1471915415; called by muse, mutect2
- SORCS3 | c.2191G>C p.A731P | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV63798361; called by muse, mutect2
- SORCS3 | c.2329C>A p.P777T | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV63793732; called by muse, mutect2
- SPANXD | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 48/510 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65152753; called by muse, mutect2
- SPATA31A6 | c.1975C>A p.L659I | Missense Mutation (SNP) | VAF 64/719 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs751781569; called by muse, mutect2
- SSPOP | n.1910-1G>C | Splice Site (SNP) | VAF 12/235 reads (5%) | catalogued as COSV100022058; called by muse, mutect2
- STYXL1 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs368425776, COSV50391334; called by muse, mutect2
- TENM1 | c.7191C>A p.N2397K | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1236772657; called by muse, mutect2
- TMEM132C | c.910G>T p.G304* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as COSV101473712; called by muse, varscan2
- TMEM132D | c.2041C>A p.Q681K | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1565956258; called by muse, mutect2, varscan2
- TNFSF11 | c.738C>A p.S246R | Missense Mutation (SNP) | VAF 30/409 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs1224826165; called by muse, mutect2
- TNN | c.3004G>T p.G1002C | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53436991; called by muse, mutect2
- TPM3 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as rs765337829; called by muse, mutect2
- TRA2A | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.048); catalogued as COSV51719296; called by muse, mutect2
- TRAK2 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60274290; called by muse, mutect2
- TRGV2 | c.95A>T p.Q32L | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs377341546; called by muse, mutect2, varscan2
- TRIM42 | c.803C>A p.S268* | Nonsense Mutation (SNP) | VAF 37/325 reads (11%) | catalogued as COSV53883578; called by muse, mutect2, varscan2
- TROAP | c.1277G>T p.S426I | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV57745690; called by muse, mutect2, varscan2
- TTC22 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 26/367 reads (7%) | catalogued as COSV100988195; called by muse, mutect2
- USH2A | c.10751C>A p.A3584D | Missense Mutation (SNP) | VAF 34/462 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as COSV56339121; called by muse, mutect2
- VPS13A | c.1829A>T p.E610V | Missense Mutation (SNP) | VAF 52/472 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs1248535974; called by muse, mutect2, varscan2
- WDR97 | c.2394G>T p.R798S | Missense Mutation (SNP) | VAF 37/474 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs1037997860; called by muse, mutect2
- WNK3 | c.3094C>A p.L1032I | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as COSV63615117; called by muse, mutect2, varscan2
- XIRP2 | c.3985G>T p.E1329* (on ENST00000628543; = p.E1504* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 19/256 reads (7%) | catalogued as COSV54714757; called by muse, mutect2
- ZMAT1 | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 21/285 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV65660396; called by muse, mutect2
- ZNF284 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV101398955; called by muse, mutect2, varscan2
- ZNF521 | c.368G>C p.C123S | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833636; called by muse, mutect2
- ZNF554 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV57886616; called by muse, mutect2, varscan2
- ZSCAN26 | c.778G>T p.E260* (on ENST00000623276 / NM_001111039.2; = p.E126* on NM_152736.5) | Nonsense Mutation (SNP) | VAF 28/163 reads (17%) | catalogued as rs569619601; called by muse, mutect2, varscan2
- A1BG | c.1136T>A p.L379Q | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.029); called by mutect2, varscan2
- ABCB5 | c.175G>T p.G59* | Nonsense Mutation (SNP) | VAF 34/446 reads (8%) | called by muse, mutect2
- ABCC9 | c.3316C>A p.H1106N | Missense Mutation (SNP) | VAF 62/392 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- ABCG5 | c.1501T>A p.Y501N | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.674); called by muse, mutect2
- ABCG5 | c.222G>T p.L74F | Missense Mutation (SNP) | VAF 49/600 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, mutect2
- ACAN | c.1639G>C p.G547R | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSBG1 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ACTA1 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTR3 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- ACTR3 | c.862G>C p.A288P | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.707); called by muse, varscan2
- ADAMTS13 | c.3328G>T p.A1110S | Missense Mutation (SNP) | VAF 23/226 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ADAMTS16 | c.3026_3027insC p.A1010Gfs*5 | Frame Shift Ins (INS) | VAF 31/236 reads (13%) | called by mutect2, pindel, varscan2
- ADCY8 | c.1443C>A p.C481* | Nonsense Mutation (SNP) | VAF 23/291 reads (8%) | called by muse, mutect2
- ADGRB1 | c.2578C>G p.P860A | Missense Mutation (SNP) | VAF 27/302 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- AFF2 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AFF3 | c.1171G>T p.A391S | Missense Mutation (SNP) | VAF 25/383 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.23); called by muse, mutect2
- AHNAK2 | c.4732A>T p.K1578* | Nonsense Mutation (SNP) | VAF 28/394 reads (7%) | called by muse, mutect2
- AKAP12 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AL391261.1 | n.213G>T | Splice Region (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- ALDH1L2 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 78/414 reads (19%) | called by muse, varscan2
- ALS2 | c.3256G>T p.E1086* | Nonsense Mutation (SNP) | VAF 34/532 reads (6%) | called by muse, mutect2
- ANO2 | c.715G>T p.E239* (on ENST00000356134 / NM_001278597.3; = p.E243* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 55/407 reads (14%) | called by muse, mutect2, varscan2
- ARID2 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 50/248 reads (20%) | called by muse, mutect2, varscan2
- ARPP21 | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 34/487 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); called by muse, mutect2
- ARVCF | c.1111G>T p.V371L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.02); called by mutect2, varscan2
- ASB1 | c.437C>A p.T146N | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- ASB5 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BBS12 | c.835G>C p.D279H | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- BIVM-ERCC5 | c.2630G>T p.S877I | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.201); called by muse, mutect2
- BMP10 | c.797G>T p.R266M | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- BMS1 | c.3725A>T p.K1242M | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BRCC3 | c.113G>T p.C38F | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.057); called by muse, mutect2
- BUB1 | c.3108del p.N1037Ifs*14 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- C10orf71 | c.2006A>T p.E669V | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- C1orf87 | c.1153A>T p.T385S | Missense Mutation (SNP) | VAF 14/386 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- C2orf42 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C6orf118 | c.353T>A p.L118Q | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CACNA1F | c.3977C>A p.A1326D | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA2D4 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 36/266 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CAMK2B | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- CASK | c.2170G>C p.D724H (on ENST00000378163 / NM_001367721.1; = p.X719_splice on NM_003688.3) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC160 | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 18/316 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2
- CCNB3 | c.3375C>A p.F1125L | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2
- CCP110 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2
- CCT8L2 | c.1082T>A p.V361E | Missense Mutation (SNP) | VAF 17/295 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- CCZ1 | c.618C>G p.I206M | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- CDC14C | c.1625G>T p.W542L (on ENST00000428251; = p.W435L on NM_152627.3) | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- CDH10 | c.2055G>T p.K685N | Missense Mutation (SNP) | VAF 49/906 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.248); called by muse, mutect2
- CDH22 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- CELSR3 | c.4901A>T p.D1634V | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- CEP128 | c.1745A>G p.K582R | Missense Mutation (SNP) | VAF 22/532 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.009); called by muse, mutect2
- CEP192 | c.5196G>T p.Q1732H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- CEP85 | c.817A>G p.T273A | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- CFAP44 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CFAP61 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CGA | c.319C>A p.H107N | Missense Mutation (SNP) | VAF 25/491 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- CHCHD3 | c.329G>T p.R110M | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CHRM4 | c.1128G>C p.K376N | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); called by muse, mutect2
- CHST1 | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CLEC4M | c.215-1G>T p.X72_splice | Splice Site (SNP) | VAF 14/108 reads (13%) | called by muse, varscan2
- COL11A1 | c.4595C>A p.P1532H | Missense Mutation (SNP) | VAF 22/583 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- COL11A1 | c.2413G>T p.G805C | Missense Mutation (SNP) | VAF 47/523 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL19A1 | c.1626+1G>T p.X542_splice | Splice Site (SNP) | VAF 12/188 reads (6%) | called by muse, mutect2
- COL23A1 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 22/235 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL24A1 | c.4019C>G p.S1340* | Nonsense Mutation (SNP) | VAF 32/307 reads (10%) | called by muse, mutect2, varscan2
- COL5A3 | c.3811G>T p.G1271* | Nonsense Mutation (SNP) | VAF 8/87 reads (9%) | called by muse, mutect2
- COL6A3 | c.6835G>T p.G2279* | Nonsense Mutation (SNP) | VAF 28/452 reads (6%) | called by muse, mutect2
- COL6A3 | c.3170G>T p.S1057I | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- COL7A1 | c.775G>T p.V259L | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.426); called by muse, mutect2
- CPA2 | c.1184A>G p.Q395R | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CPXCR1 | c.641C>A p.S214* | Nonsense Mutation (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- CRISP2 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 26/339 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRY1 | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CSMD3 | c.3584G>T p.G1195V (on ENST00000297405 / NM_001363185.1; = p.G1091V on NM_052900.3) | Missense Mutation (SNP) | VAF 46/704 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CSPG4 | c.2824C>A p.H942N | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- CTAGE6 | c.1266G>T p.K422N | Missense Mutation (SNP) | VAF 42/1163 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2
- CUX2 | c.2810G>T p.R937L | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF12L2 | c.933C>A p.C311* | Nonsense Mutation (SNP) | VAF 22/306 reads (7%) | called by muse, mutect2
- DCDC1 | c.2486C>A p.S829* | Nonsense Mutation (SNP) | VAF 34/312 reads (11%) | called by muse, mutect2, varscan2
- DCTN1 | c.1801G>T p.G601W | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDC | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 38/646 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2
- DDX21 | c.2125A>T p.T709S | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.241); called by muse, mutect2
- DDX25 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DDX4 | c.1200T>G p.Y400* | Nonsense Mutation (SNP) | VAF 31/263 reads (12%) | called by muse, mutect2, varscan2
- DDX60L | c.4485+1del p.X1495_splice | Splice Site (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- DGKK | c.1578G>T p.K526N | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.976); called by muse, mutect2
- DISC1 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 38/502 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DLX6 | c.751C>A p.L251M | Missense Mutation (SNP) | VAF 36/594 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.085); called by muse, mutect2
- DNAH9 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DOK6 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.287); called by muse, mutect2
- DPY19L2 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- DSP | c.5848C>A p.H1950N | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2
- DST | c.17237G>T p.G5746V (on ENST00000361203 / NM_001374722.1; = p.G3443V on NM_015548.5) | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DVL3 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 61/438 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- E2F3 | c.651G>T p.R217S | Missense Mutation (SNP) | VAF 27/463 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EBF3 | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.441); called by muse, mutect2
- EDEM2 | c.1631G>T p.R544M | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- EMILIN2 | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.101); called by mutect2, varscan2
- EP400 | c.6113G>T p.G2038V | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EPC1 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPHB6 | c.1703G>C p.G568A | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2
- ERICH3 | c.4168C>A p.Q1390K | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EXO1 | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- EYS | c.1823G>C p.C608S | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- F13B | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 20/311 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM171B | c.1567G>T p.G523W | Missense Mutation (SNP) | VAF 9/275 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FAM207A | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2
- FAM47E | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2
- FAM71E2 | c.2185G>T p.A729S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT2 | c.183C>A p.Y61* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- FAT3 | c.5317C>G p.Q1773E | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- FAT3 | c.9329G>T p.G3110V | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBXO7 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.524); called by muse, mutect2
- FCRLA | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2
- FGFR4 | c.1653G>T p.E551D | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FIGNL2 | c.487G>A p.G163S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2
- FLG | c.9420C>A p.H3140Q | Missense Mutation (SNP) | VAF 30/569 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2
- FLNB | c.3284G>T p.C1095F | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- FOLH1 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- FSIP2 | c.7510C>A p.H2504N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.223); called by muse, mutect2
- FUNDC2 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FZD5 | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GAB3 | c.189C>A p.S63R | Missense Mutation (SNP) | VAF 39/524 reads (7%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.922); called by muse, mutect2
- GABPA | c.1141T>G p.Y381D | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRG2 | c.1403C>A p.A468D (on ENST00000361925 / NM_001375343.1; = p.A428D on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/565 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAGE12H | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 51/1014 reads (5%) | called by muse, mutect2
- GDI1 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 28/367 reads (8%) | called by muse, mutect2
- GPHN | c.1390A>G p.I464V (on ENST00000315266 / NM_001377519.1; = p.I497V on NM_020806.5) | Missense Mutation (SNP) | VAF 37/443 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2
- GPNMB | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 28/457 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.23); called by muse, mutect2
- GPR158 | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GREM2 | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2
- GRHL3 | c.1856T>C p.L619P | Missense Mutation (SNP) | VAF 9/32 reads (28%) | PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- GRM1 | c.2752A>G p.K918E | Missense Mutation (SNP) | VAF 22/573 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.152); called by muse, mutect2
- GRP | c.224T>A p.I75N | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.416); called by muse, mutect2
- GSG1L | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- H1-8 | c.931del p.V311Yfs*? | Frame Shift Del (DEL) | VAF 26/268 reads (10%) | called by mutect2, pindel, varscan2
- HBE1 | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HCN1 | c.2151C>A p.F717L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HDAC6 | c.2765A>T p.Q922L | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- HEMGN | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- HEPACAM2 | c.882G>C p.K294N (on ENST00000394468 / NM_001039372.4; = p.K282N on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2
- HERC2 | c.11076C>G p.I3692M | Missense Mutation (SNP) | VAF 32/401 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2
- HGD | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 43/476 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- HGH1 | c.885G>A p.L295= | Splice Region (SNP) | VAF 85/862 reads (10%) | called by muse, mutect2
- HIVEP3 | c.1955A>G p.Y652C | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HK3 | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.5); called by muse, mutect2
- HMGCS2 | c.819C>A p.Y273* | Nonsense Mutation (SNP) | VAF 47/440 reads (11%) | called by muse, mutect2, varscan2
- HOMER2 | c.783del p.E262Kfs*6 (on ENST00000304231 / NM_199330.3; = p.E251Kfs*6 on NM_004839.4) | Frame Shift Del (DEL) | VAF 20/146 reads (14%) | called by mutect2, varscan2
- HRNR | c.6194C>A p.S2065Y | Missense Mutation (SNP) | VAF 39/626 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2
- HS6ST1 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HTATSF1 | c.1759G>T p.V587F | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- IARS1 | c.1954G>T p.V652L | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); called by muse, mutect2
- IGHV3-35 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 61/600 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- IGLV2-14 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- IGLV2-23 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 39/587 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IL31RA | c.2030G>T p.R677M | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- IL31RA | c.2031G>T p.R677S | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- INSYN2B | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- INTS2 | c.349A>T p.I117F | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); called by muse, mutect2
- ITGA3 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ITIH6 | c.1703C>A p.T568N | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ITLN2 | c.878G>T p.G293V | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- JAKMIP1 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 15/139 reads (11%) | called by muse, varscan2
- KATNIP | c.3631+3G>T | Splice Region (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- KCND1 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- KCNMA1 | c.2522A>T p.H841L (on ENST00000286628 / NM_001161352.2; = p.H783L on NM_002247.4) | Missense Mutation (SNP) | VAF 37/467 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- KCTD5 | c.362G>C p.G121A | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- KIAA1109 | c.13308G>T p.Q4436H | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIAA1549L | c.5024C>A p.P1675Q (on ENST00000321505; = p.P1972Q on NM_012194.3) | Missense Mutation (SNP) | VAF 35/362 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- KIAA2012 | c.727C>A p.H243N | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.153); called by muse, mutect2
- KIR3DL2 | c.1072T>A p.F358I | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2
- KLHL13 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.052); called by muse, mutect2
- KLHL21 | c.1475G>T p.W492L | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- KMT2D | c.15785C>T p.A5262V | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- L1CAM | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.205); called by muse, mutect2
- LAMA1 | c.6917C>T p.P2306L | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- LAMA5 | c.8387dup p.V2797Cfs*5 | Frame Shift Ins (INS) | VAF 12/91 reads (13%) | called by mutect2, pindel, varscan2
- LAMB1 | c.4931C>A p.A1644E | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LCE3A | c.138C>A p.S46R | Missense Mutation (SNP) | VAF 48/526 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2
- LEUTX | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- LGR4 | c.2336C>A p.P779H | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LIMCH1 | c.2021C>G p.A674G | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.214); called by muse, mutect2
- LOXL3 | c.365C>A p.T122N | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.096); called by muse, mutect2
- LPA | c.3587C>T p.T1196I | Missense Mutation (SNP) | VAF 48/578 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.048); called by muse, mutect2
- LRIG2 | c.638A>T p.K213M | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- LRP1B | c.5515C>T p.Q1839* | Nonsense Mutation (SNP) | VAF 25/258 reads (10%) | called by muse, mutect2
- LRP2 | c.8453C>A p.P2818H | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- LRRIQ4 | c.64C>G p.H22D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by muse, mutect2
- LRRTM3 | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- LRRTM4 | c.713G>T p.W238L | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRTM2 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LY9 | c.1026G>T p.E342D | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.095); called by muse, mutect2
- MAGEC1 | c.1204G>T p.G402C | Missense Mutation (SNP) | VAF 33/543 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- MAGEC1 | c.2722C>A p.L908M | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- MAP2 | c.5442G>T p.L1814F | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP3K19 | c.827C>A p.T276N | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2
- MAP3K7 | c.554A>T p.H185L | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- MAP7D3 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2
- MBD5 | c.3504G>T p.K1168N | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2
- MBD5 | c.3505A>T p.N1169Y | Missense Mutation (SNP) | VAF 34/504 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); called by muse, mutect2
- MCM4 | c.2173G>T p.G725* | Nonsense Mutation (SNP) | VAF 16/175 reads (9%) | called by muse, mutect2
- MDFIC | c.217+1G>T p.X73_splice | Splice Site (SNP) | VAF 15/130 reads (12%) | called by muse, mutect2
- MGAM2 | c.187-1G>T p.X63_splice | Splice Site (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- MGAM2 | c.4098C>A p.S1366R | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MMP1 | c.1249C>A p.H417N | Missense Mutation (SNP) | VAF 12/310 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- MMP13 | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MMP2 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- MMP2 | c.1539G>T p.W513C | Missense Mutation (SNP) | VAF 22/713 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MRGPRX1 | c.911G>T p.G304V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MS4A2 | c.242C>A p.S81Y | Missense Mutation (SNP) | VAF 33/545 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.694); called by muse, mutect2
- MTERF3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- MTM1 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 18/503 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2
- MTMR14 | c.965-2A>G p.X322_splice | Splice Site (SNP) | VAF 36/334 reads (11%) | called by muse, mutect2, varscan2
- MUC17 | c.2553A>T p.E851D | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- MUC17 | c.4969G>A p.D1657N | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.313); called by muse, mutect2
- MUC5AC | c.16558C>A p.P5520T | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.755); called by muse, mutect2
- MYH1 | c.4361A>T p.D1454V | Missense Mutation (SNP) | VAF 53/393 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.3709C>A p.L1237I | Missense Mutation (SNP) | VAF 46/376 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- MYH4 | c.2436A>T p.R812S | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); called by muse, varscan2
- MYH7 | c.2843C>A p.S948* | Nonsense Mutation (SNP) | VAF 60/736 reads (8%) | called by muse, mutect2
- MYLIP | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO18B | c.2245C>A p.Q749K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYO9B | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- MYOM1 | c.1970G>T p.S657I | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MYPN | c.2157C>G p.S719R | Missense Mutation (SNP) | VAF 65/693 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.03); called by muse, mutect2
- MYT1 | c.884A>T p.E295V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.029); called by muse, mutect2
- NAV3 | c.5352G>T p.K1784N | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- NEU1 | c.577A>T p.T193S | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- NFATC2 | c.2587G>T p.V863F | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- NFKBIZ | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.2638C>A p.H880N | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- NOTCH4 | c.4138G>T p.G1380W | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- NPY2R | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- NRIP1 | c.2740G>T p.G914C | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NVL | c.1936G>C p.V646L | Missense Mutation (SNP) | VAF 40/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- OBSCN | c.7916del p.R2639Pfs*6 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- OBSCN | c.10918G>T p.G3640W | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OLR1 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- OMD | c.280C>A p.Q94K | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.081); called by muse, mutect2
- OPRM1 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.139); called by muse, mutect2
- OR10Q1 | c.455C>A p.A152D | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2
- OR13G1 | c.283A>G p.M95V | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.265); called by muse, mutect2
- OR2B11 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- OR2L5 | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 26/563 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- OR2L5 | c.233C>A p.P78H | Missense Mutation (SNP) | VAF 27/565 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- OR2L8 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR2M5 | c.845C>A p.T282N | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T11 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.439); called by muse, mutect2
- OR4D5 | c.363C>G p.D121E | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D13 | c.376G>A p.V126M | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2
- OR5L1 | c.550G>T p.V184F | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2
- OR5T1 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR6K2 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.05); called by muse, mutect2
- OSBPL1A | c.1443A>G p.S481= | Splice Region (SNP) | VAF 7/145 reads (5%) | called by muse, mutect2
- OTOG | c.6596C>A p.P2199Q | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- OTOP1 | c.396G>C p.W132C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OTUD5 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- OTUD6A | c.585C>A p.S195R | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- PACRG | c.765G>T p.Q255H | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PADI6 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2
- PAFAH1B2 | c.214G>T p.G72* | Nonsense Mutation (SNP) | VAF 21/232 reads (9%) | called by muse, mutect2, varscan2
- PAPPA2 | c.3694C>A p.L1232I | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- PARP9 | c.1439G>T p.S480I | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PBRM1 | c.1187G>T p.C396F | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.105); called by muse, mutect2
- PCDH7 | c.2587G>T p.D863Y | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2
- PCDHA4 | c.890C>A p.P297Q | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- PCDHGA1 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDCD11 | c.2832G>T p.L944F | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- PDE10A | c.767A>T p.Q256L | Missense Mutation (SNP) | VAF 15/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PDE1C | c.745G>T p.V249L | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PDILT | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- PENK | c.279C>G p.S93R | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- PEX5L | c.629G>A p.W210* | Nonsense Mutation (SNP) | VAF 21/185 reads (11%) | called by muse, mutect2, varscan2
- PICALM | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PIGK | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- PIK3C2G | c.2203G>T p.V735F (on ENST00000676171; = p.V694F on NM_004570.5) | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PLCB4 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PLEKHG4B | c.2231A>T p.Q744L (on ENST00000283426; = p.Q1100L on NM_052909.5) | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.047); called by muse, mutect2
- PLG | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PLXNA2 | c.746G>T p.S249I | Missense Mutation (SNP) | VAF 32/466 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNA3 | c.3170G>T p.R1057L | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLXNA3 | c.3469G>T p.G1157C | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- POLN | c.517G>C p.A173P | Missense Mutation (SNP) | VAF 21/288 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.77); called by muse, mutect2
- POMT2 | c.819G>T p.V273= | Splice Region (SNP) | VAF 28/616 reads (5%) | called by muse, mutect2
- PPP3R2 | c.132G>C p.M44I | Missense Mutation (SNP) | VAF 17/344 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- PRKN | c.670G>A p.V224I | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- PRR32 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- PSKH2 | c.1098G>T p.R366S | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- PTPRC | c.2237C>G p.T746R | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPRD | c.5699C>A p.A1900E | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- PTPRD | c.2568C>A p.Y856* | Nonsense Mutation (SNP) | VAF 23/252 reads (9%) | called by muse, mutect2
- PTPRT | c.4272+1G>T p.X1424_splice | Splice Site (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- QSER1 | c.4576G>T p.D1526Y (on ENST00000399302; = p.D1655Y on NM_001076786.3) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RAE1 | c.488C>G p.P163R | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- RASL10B | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 17/143 reads (12%) | called by muse, mutect2, varscan2
- RAVER2 | c.647A>T p.Q216L | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RBAK | c.1269C>A p.H423Q | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RBP3 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 24/244 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- RBP3 | c.2357C>A p.P786H | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); called by muse, mutect2
- RFTN2 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.132); called by muse, mutect2
- RGN | c.634G>T p.G212W | Missense Mutation (SNP) | VAF 24/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIPOR2 | c.932T>A p.L311Q | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RP1 | c.2140G>T p.V714L | Missense Mutation (SNP) | VAF 35/454 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RP1 | c.2114G>T p.S705I | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2
- RYR1 | c.4702C>G p.Q1568E | Missense Mutation (SNP) | VAF 64/378 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- SAP30L | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.137); called by muse, mutect2
- SCNN1D | c.523T>A p.S175T (on ENST00000338555; = p.S339T on NM_001130413.4) | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.216); called by muse, mutect2
- SEC23A | c.1309-2A>T p.X437_splice | Splice Site (SNP) | VAF 38/426 reads (9%) | called by muse, mutect2
- SEMA3A | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 37/485 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.036); called by muse, mutect2
- SEPTIN14 | c.1039A>T p.R347W | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- SETD1B | c.2636A>T p.D879V | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SF3B1 | c.811G>T p.G271C | Missense Mutation (SNP) | VAF 20/510 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- SHISA3 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SHROOM4 | c.2879G>C p.R960T | Missense Mutation (SNP) | VAF 12/305 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.351); called by muse, mutect2
- SI | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- SIRT6 | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SKOR2 | c.537G>T p.M179I | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2
- SLAMF1 | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 23/428 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2
- SLC16A7 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC35F3 | c.63_64insT p.R22* | Frame Shift Ins (INS) | VAF 6/65 reads (9%) | called by mutect2, pindel*
- SLC52A2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2
- SLC6A2 | c.797C>A p.T266K | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- SLCO1A2 | c.590-1G>T p.X197_splice | Splice Site (SNP) | VAF 52/204 reads (25%) | called by muse, mutect2, varscan2
- SLCO1B1 | c.1580A>T p.D527V | Missense Mutation (SNP) | VAF 13/383 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2
- SLCO4C1 | c.2096T>C p.V699A | Missense Mutation (SNP) | VAF 30/490 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2
- SLCO5A1 | c.1646G>T p.R549M | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.117); called by muse, mutect2
- SLIT2 | c.952G>C p.G318R | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); called by muse, mutect2
- SMC1A | c.3583A>G p.T1195A | Missense Mutation (SNP) | VAF 40/409 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SMIM10 | c.70G>T p.G24C | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2
- SMO | c.2120T>A p.L707Q | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- SNTG1 | c.1151C>A p.A384D | Missense Mutation (SNP) | VAF 30/379 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SNX27 | c.1577A>T p.E526V | Missense Mutation (SNP) | VAF 14/309 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2
- SORCS1 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- SOX6 | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 26/294 reads (9%) | called by muse, mutect2
- SPATA31D1 | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 50/681 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2
- SPHKAP | c.1101C>A p.N367K | Missense Mutation (SNP) | VAF 9/173 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- SPTAN1 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 76/526 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- STAU2 | c.1067C>T p.P356L (on ENST00000524300 / NM_001164380.2; = p.P324L on NM_014393.2) | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.098); called by muse, mutect2
- SULT1B1 | c.325C>A p.H109N | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SVOP | c.512C>A p.P171H | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYMPK | c.101A>T p.E34V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- SYNPO2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- TAP2 | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 50/678 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.173); called by muse, mutect2
- TAS2R39 | c.872T>C p.L291P | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- TCERG1L | c.554T>G p.F185C | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- TECPR1 | c.2653G>T p.D885Y | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TECTA | c.3681C>G p.I1227M | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, mutect2
- THAP3 | c.691G>A p.A231T (on ENST00000054650 / NM_001195753.1; = p.A230T on NM_001195752.1) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2
- TIAM2 | c.2082G>T p.M694I | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.225); called by muse, mutect2
- TIAM2 | c.3210C>G p.D1070E | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- TIMD4 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 32/494 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- TLDC2 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM33 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); called by muse, mutect2
- TMEM51 | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMPRSS9 | c.667T>A p.C223S (on ENST00000648592; = p.C189S on NM_182973.2) | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.337); called by muse, mutect2
- TOGARAM1 | c.3457G>T p.V1153F | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- TRAF3IP3 | c.973C>A p.L325M | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- TRAV12-2 | c.238G>T p.G80* | Nonsense Mutation (SNP) | VAF 35/417 reads (8%) | called by muse, mutect2
- TRBV24-1 | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.029); called by muse, mutect2
- TREML4 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2
- TRIB2 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); called by muse, mutect2
- TRIM49B | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- TRIM64C | c.275G>C p.C92S | Missense Mutation (SNP) | VAF 46/799 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TSC22D1 | c.2971G>T p.V991L (on ENST00000458659 / NM_183422.4; = p.V62L on NM_006022.4) | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSHR | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 43/580 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.029); called by muse, mutect2
- TTC14 | c.1793G>C p.R598T | Missense Mutation (SNP) | VAF 20/299 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2
- TTC6 | c.1224T>G p.S408R | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.364); called by muse, mutect2
- TTC7B | c.1876G>T p.G626* | Nonsense Mutation (SNP) | VAF 36/333 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.65056C>A p.P21686T (on ENST00000591111; = p.P14262T on NM_003319.4) | Missense Mutation (SNP) | VAF 5/66 reads (8%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- UBC | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 122/1006 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, varscan2
- UBE2F | c.553A>G p.R185G | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- UGT2B17 | c.636A>G p.I212M | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2
- UHRF1BP1L | c.2969G>T p.G990V | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- UNC79 | c.4109G>T p.C1370F (on ENST00000393151 / NM_001346218.2; = p.C1193F on NM_020818.5) | Missense Mutation (SNP) | VAF 35/341 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- UNC80 | c.3460G>T p.G1154C | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UNC80 | c.3838T>C p.W1280R | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UPK1A | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USH2A | c.6899G>A p.S2300N | Missense Mutation (SNP) | VAF 41/426 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- VCL | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 23/789 reads (3%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.521); called by muse, mutect2
- VN1R5 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- VPS41 | c.2338A>T p.M780L | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- VWA5B2 | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- VWDE | c.4187G>T p.R1396M | Missense Mutation (SNP) | VAF 14/263 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- WNT16 | c.837C>G p.I279M (on ENST00000222462 / NM_057168.2; = p.I269M on NM_016087.2) | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.844); called by muse, mutect2
- WSCD1 | c.897C>A p.Y299* | Nonsense Mutation (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- WWP1 | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 36/568 reads (6%) | SIFT tolerated (0.87); PolyPhen benign (0.246); called by muse, mutect2
- XIRP2 | c.2588T>C p.I863T (on ENST00000628543; = p.I1038T on NM_152381.6) | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2
- XRN1 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 48/400 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, varscan2
- ZBTB48 | c.231G>T p.L77F | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ZDBF2 | c.5140G>T p.A1714S | Missense Mutation (SNP) | VAF 14/341 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2
- ZFPM2 | c.2650C>G p.R884G | Missense Mutation (SNP) | VAF 40/519 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.145); called by muse, mutect2
- ZIC3 | c.970G>T p.G324C | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZMYM2 | c.1184A>G p.E395G | Missense Mutation (SNP) | VAF 18/305 reads (6%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.969); called by muse, mutect2
- ZNF221 | c.228A>T p.Q76H | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2
- ZNF391 | c.244G>T p.G82* | Nonsense Mutation (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- ZNF419 | c.561T>A p.H187Q | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.88); called by muse, mutect2
- ZNF766 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.337); called by muse, varscan2
- ZPLD1 | c.220C>A p.H74N (on ENST00000466937 / NM_001329788.1; = p.H90N on NM_175056.2) | Missense Mutation (SNP) | VAF 59/534 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- AC231657.3 | c.690C>G p.V230= | Silent (SNP) | VAF 19/292 reads (7%) | called by muse, mutect2
- ADAMTS16 | c.936C>A p.T312= | Silent (SNP) | VAF 62/345 reads (18%) | called by muse, mutect2, varscan2
- AFF2 | c.285G>T p.V95= | Silent (SNP) | VAF 23/363 reads (6%) | called by muse, mutect2
- ANKS1B | c.606G>T p.A202= | Silent (SNP) | VAF 95/396 reads (24%) | called by muse, mutect2, varscan2
- APPL1 | c.1836G>C p.G612= | Silent (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- ARFGEF3 | c.1668G>T p.A556= | Silent (SNP) | VAF 14/388 reads (4%) | catalogued as COSV99292166; called by muse, mutect2
- ATRN | c.357C>G p.V119= | Silent (SNP) | VAF 6/33 reads (18%) | called by muse, varscan2
- BCORL1 | c.1035G>T p.T345= | Silent (SNP) | VAF 12/231 reads (5%) | called by muse, mutect2
- BCR | c.2787G>A p.L929= | Silent (SNP) | VAF 53/512 reads (10%) | catalogued as rs747942634; called by muse, mutect2, varscan2
- CALHM3 | c.894G>T p.V298= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, varscan2
- CASZ1 | c.1011C>T p.S337= | Silent (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- CD163 | c.535C>A p.R179= | Silent (SNP) | VAF 48/196 reads (24%) | catalogued as COSV63131936, COSV63133746; called by muse, mutect2, varscan2
- CDH7 | c.699G>A p.K233= | Silent (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- CFAP47 | c.5178C>A p.P1726= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs765991520; called by mutect2, varscan2
- COL20A1 | c.981G>T p.A327= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- CYP3A4 | c.1464C>A p.I488= (on ENST00000336411; = p.I457= on NM_017460.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as COSV60501411; called by muse, mutect2
- DGAT2L6 | c.603C>T p.F201= | Silent (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
- DGKK | c.2490C>G p.L830= | Silent (SNP) | VAF 15/290 reads (5%) | called by muse, mutect2
- DLG2 | c.417C>A p.A139= (on ENST00000650630 / NM_001351274.2; = p.A102= on NM_001142699.3) | Silent (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- DMD | c.1824G>T p.A608= | Silent (SNP) | VAF 22/298 reads (7%) | called by muse, mutect2
- DNAH10 | c.10812T>A p.A3604= (on ENST00000409039; = p.A3543= on NM_207437.3) | Silent (SNP) | VAF 18/82 reads (22%) | called by mutect2, varscan2
- DPPA2 | c.603T>A p.A201= | Silent (SNP) | VAF 31/244 reads (13%) | called by muse, mutect2, varscan2
- DST | c.5553C>T p.V1851= | Silent (SNP) | VAF 26/201 reads (13%) | catalogued as COSV99759553; called by muse, mutect2, varscan2
- DVL1 | c.651G>T p.R217= | Silent (SNP) | VAF 19/177 reads (11%) | called by muse, mutect2, varscan2
- ECD | c.1089A>T p.A363= | Silent (SNP) | VAF 16/421 reads (4%) | called by muse, mutect2
- EEF1AKMT4-ECE2 | c.2532C>A p.P844= | Silent (SNP) | VAF 23/188 reads (12%) | called by muse, mutect2, varscan2
- EHBP1L1 | c.2181G>A p.Q727= | Silent (SNP) | VAF 13/299 reads (4%) | called by muse, mutect2
- ELN | c.1290A>G p.G430= | Silent (SNP) | VAF 20/293 reads (7%) | called by muse, mutect2
- EPHA10 | c.216C>T p.R72= | Silent (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- FAM135B | c.1836C>A p.L612= | Silent (SNP) | VAF 20/291 reads (7%) | catalogued as COSV52725989; called by muse, mutect2
- FCRL4 | c.438T>A p.S146= | Silent (SNP) | VAF 27/316 reads (9%) | catalogued as COSV99619395; called by muse, mutect2
- FGR | c.417C>A p.I139= | Silent (SNP) | VAF 10/235 reads (4%) | catalogued as COSV64969170; called by muse, mutect2
- FKBP6 | c.294C>A p.G98= | Silent (SNP) | VAF 37/422 reads (9%) | called by muse, mutect2
- FLNA | c.3252C>A p.S1084= | Silent (SNP) | VAF 20/121 reads (17%) | called by muse, mutect2, varscan2
- FLRT2 | c.468G>T p.R156= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- FOXD2 | c.441G>T p.R147= | Silent (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- FSIP2 | c.7509C>A p.G2503= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- GLYAT | c.618C>A p.T206= | Silent (SNP) | VAF 38/334 reads (11%) | catalogued as COSV53540396; called by muse, mutect2
- GPR83 | c.576C>A p.V192= | Silent (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- GPR88 | c.594C>A p.A198= | Silent (SNP) | VAF 29/199 reads (15%) | called by muse, mutect2, varscan2
- H2BW2 | c.339C>G p.T113= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- HAPLN4 | c.873C>T p.R291= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs1331641635; called by muse, mutect2, varscan2
- HJV | c.297G>T p.G99= | Silent (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- HLCS | c.624C>T p.D208= | Silent (SNP) | VAF 18/236 reads (8%) | catalogued as rs143358508; called by muse, mutect2
- HMCN2 | c.465C>A p.L155= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- HNRNPCL2 | c.501G>T p.R167= | Silent (SNP) | VAF 16/442 reads (4%) | called by muse, mutect2
- HOXA6 | c.388C>A p.R130= | Silent (SNP) | VAF 13/150 reads (9%) | catalogued as rs911817057; called by muse, mutect2
- HTR1A | c.534G>A p.P178= | Silent (SNP) | VAF 34/402 reads (8%) | catalogued as COSV60500021, COSV60501567; called by muse, mutect2
- HUWE1 | c.396G>T p.L132= | Silent (SNP) | VAF 18/300 reads (6%) | called by muse, mutect2
- IGHV3-20 | c.204T>C p.S68= | Silent (SNP) | VAF 49/518 reads (9%) | catalogued as rs915507882; called by muse, mutect2, varscan2
- IGHV3-7 | c.54G>A p.Q18= | Silent (SNP) | VAF 22/245 reads (9%) | catalogued as rs546086999; called by muse, mutect2
- IGKV1-5 | c.138G>T p.R46= | Silent (SNP) | VAF 52/694 reads (7%) | called by muse, mutect2
- IMPG1 | c.687T>A p.A229= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- ITGA4 | c.2931C>A p.T977= | Silent (SNP) | VAF 9/198 reads (5%) | called by muse, mutect2
- KCND1 | c.843G>T p.V281= | Silent (SNP) | VAF 22/352 reads (6%) | called by muse, mutect2
- KCNK2 | c.222C>T p.I74= (on ENST00000444842 / NM_001017425.3; = p.I59= on NM_014217.4) | Silent (SNP) | VAF 35/501 reads (7%) | catalogued as COSV101221805; called by muse, mutect2
- KEL | c.1105C>T p.L369= | Silent (SNP) | VAF 40/592 reads (7%) | called by muse, mutect2
- KLHL13 | c.681G>T p.L227= | Silent (SNP) | VAF 26/282 reads (9%) | called by muse, mutect2
- KRBA1 | c.1692G>T p.R564= | Silent (SNP) | VAF 12/80 reads (15%) | called by muse, varscan2
- LAMA2 | c.8565T>C p.S2855= | Silent (SNP) | VAF 47/517 reads (9%) | catalogued as rs201276440; called by muse, mutect2
- LGR4 | c.309G>T p.G103= | Silent (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- LINGO1 | c.1761C>T p.G587= | Silent (SNP) | VAF 10/224 reads (4%) | catalogued as COSV100796522; called by muse, mutect2
- LPA | c.3847C>A p.R1283= | Silent (SNP) | VAF 47/535 reads (9%) | catalogued as rs773141063, COSV60299785, COSV60311138; called by muse, mutect2
- LRRC8B | c.120G>A p.V40= | Silent (SNP) | VAF 20/456 reads (4%) | called by muse, mutect2
- LYST | c.1713C>G p.V571= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- MAG | c.564G>C p.R188= | Silent (SNP) | VAF 15/288 reads (5%) | catalogued as rs904515831; called by muse, mutect2
- MBNL3 | c.159C>A p.A53= | Silent (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- MMRN2 | c.1071G>T p.T357= | Silent (SNP) | VAF 25/240 reads (10%) | called by muse, mutect2, varscan2
- MROH2B | c.1275G>A p.E425= | Silent (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- MUC16 | c.28791C>A p.S9597= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- MUC16 | c.26508T>A p.P8836= | Silent (SNP) | VAF 34/391 reads (9%) | called by muse, mutect2
- MYOD1 | c.99G>T p.P33= | Silent (SNP) | VAF 27/189 reads (14%) | catalogued as COSV51455104, COSV51455201; called by muse, mutect2, varscan2
- MYPN | c.1257C>T p.P419= | Silent (SNP) | VAF 24/728 reads (3%) | called by muse, mutect2
- NAV3 | c.585C>T p.S195= | Silent (SNP) | VAF 52/325 reads (16%) | called by muse, mutect2, varscan2
- NCAM1 | c.792C>A p.I264= | Silent (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- NLRP13 | c.2400G>T p.L800= | Silent (SNP) | VAF 9/183 reads (5%) | catalogued as COSV61621525; called by muse, mutect2
- OAS3 | c.1140G>T p.G380= | Silent (SNP) | VAF 74/356 reads (21%) | called by muse, mutect2, varscan2
- OGT | c.2004G>T p.T668= | Silent (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- OR10A4 | c.348G>T p.L116= | Silent (SNP) | VAF 17/229 reads (7%) | catalogued as COSV101139624, COSV65842560; called by muse, mutect2
- OR10Q1 | c.456C>A p.A152= | Silent (SNP) | VAF 16/187 reads (9%) | catalogued as rs1266459660; called by muse, mutect2
- OR2M7 | c.144C>A p.L48= | Silent (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- OR4M1 | c.600C>A p.I200= | Silent (SNP) | VAF 46/516 reads (9%) | catalogued as COSV60060078, COSV60062994; called by muse, mutect2
- OR52R1 | c.741T>C p.H247= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, mutect2, varscan2
- OSBPL3 | c.2358A>G p.T786= | Silent (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- OTOG | c.4665C>A p.A1555= | Silent (SNP) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- OVCH1 | c.1632T>A p.P544= | Silent (SNP) | VAF 37/272 reads (14%) | called by muse, mutect2, varscan2
- PALD1 | c.2352C>T p.F784= | Silent (SNP) | VAF 19/209 reads (9%) | called by muse, mutect2
- PCDHB3 | c.2130G>T p.A710= | Silent (SNP) | VAF 34/311 reads (11%) | catalogued as COSV50577138; called by muse, mutect2, varscan2
- PCK1 | c.1608G>T p.V536= | Silent (SNP) | VAF 24/487 reads (5%) | called by muse, mutect2
- PFKL | c.2151G>T p.V717= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- PKD1 | c.4713G>T p.S1571= | Silent (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- PKHD1 | c.6081C>G p.V2027= | Silent (SNP) | VAF 81/743 reads (11%) | called by muse, mutect2, varscan2
- PPL | c.1758G>A p.L586= | Silent (SNP) | VAF 12/175 reads (7%) | called by muse, mutect2
- PPP1R2C | c.339G>A p.V113= | Silent (SNP) | VAF 28/402 reads (7%) | called by muse, mutect2
- PRPS1L1 | c.312G>C p.R104= | Silent (SNP) | VAF 33/242 reads (14%) | catalogued as COSV72650028; called by muse, mutect2, varscan2
- PRR14L | c.1383C>T p.P461= | Silent (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- RAB11FIP5 | c.99C>T p.G33= | Silent (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- RDH8 | c.711G>T p.R237= (on ENST00000651512; = p.R217= on NM_015725.4) | Silent (SNP) | VAF 21/317 reads (7%) | called by muse, mutect2
- RELN | c.9942C>A p.I3314= | Silent (SNP) | VAF 50/451 reads (11%) | called by muse, mutect2, varscan2
- RGSL1 | c.1659G>A p.E553= | Silent (SNP) | VAF 25/358 reads (7%) | called by muse, mutect2
- RP1L1 | c.651G>T p.L217= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- RTL3 | c.879C>A p.L293= | Silent (SNP) | VAF 23/220 reads (10%) | called by muse, mutect2, varscan2
- RXFP3 | c.921G>T p.A307= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV57503839; called by muse, mutect2, varscan2
- RYR2 | c.10155A>T p.L3385= | Silent (SNP) | VAF 28/422 reads (7%) | called by muse, mutect2
- RYR3 | c.11274C>A p.G3758= (on ENST00000389232; = p.G3759= on NM_001036.6) | Silent (SNP) | VAF 13/270 reads (5%) | called by muse, mutect2
- SAMD9 | c.2802A>G p.S934= | Silent (SNP) | VAF 52/618 reads (8%) | called by muse, mutect2
- SBSN | c.258C>A p.G86= | Silent (SNP) | VAF 26/278 reads (9%) | catalogued as rs150167991; called by muse, mutect2
- SERPINB5 | c.813C>A p.L271= | Silent (SNP) | VAF 34/311 reads (11%) | called by muse, mutect2, varscan2
- SERPINE3 | c.792T>A p.R264= | Silent (SNP) | VAF 18/420 reads (4%) | called by muse, mutect2
- SLC16A14 | c.544C>T p.L182= | Silent (SNP) | VAF 21/308 reads (7%) | called by muse, mutect2
- SLC18A1 | c.57C>A p.S19= | Silent (SNP) | VAF 23/328 reads (7%) | called by muse, mutect2
- SLC22A7 | c.55C>A p.R19= | Silent (SNP) | VAF 8/73 reads (11%) | called by mutect2, varscan2
- SLC23A1 | c.849C>A p.A283= | Silent (SNP) | VAF 26/302 reads (9%) | called by muse, mutect2
- SLC25A12 | c.1515C>T p.C505= | Silent (SNP) | VAF 34/541 reads (6%) | called by muse, mutect2
- SLC2A2 | c.192A>T p.T64= | Silent (SNP) | VAF 66/496 reads (13%) | called by muse, mutect2, varscan2
- SLC30A10 | c.78G>A p.L26= | Silent (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- SLC39A4 | c.1698G>T p.A566= (on ENST00000301305 / NM_001374839.1; = p.A541= on NM_017767.3) | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- SLC6A3 | c.1365G>T p.A455= | Silent (SNP) | VAF 63/423 reads (15%) | called by muse, mutect2, varscan2
- SLC9A6 | c.405G>T p.V135= | Silent (SNP) | VAF 26/426 reads (6%) | called by muse, mutect2
- SMARCA1 | c.42C>A p.A14= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV64412324; called by mutect2, varscan2
- SPIRE1 | c.870A>G p.Q290= | Silent (SNP) | VAF 14/291 reads (5%) | catalogued as rs1484019129; called by muse, mutect2
- SPTBN4 | c.5805C>T p.R1935= | Silent (SNP) | VAF 59/349 reads (17%) | called by muse, mutect2, varscan2
- SUGP2 | c.2733G>A p.G911= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as rs766194574, COSV100431840; called by muse, mutect2, varscan2
- TENM1 | c.3564A>T p.P1188= | Silent (SNP) | VAF 46/663 reads (7%) | called by muse, mutect2
- TENM4 | c.45C>G p.R15= | Silent (SNP) | VAF 12/166 reads (7%) | called by muse, mutect2
- THSD7A | c.855G>A p.K285= | Silent (SNP) | VAF 22/240 reads (9%) | called by muse, mutect2
- TKTL2 | c.1404C>A p.T468= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- TLK1 | c.57C>A p.L19= | Silent (SNP) | VAF 31/305 reads (10%) | called by muse, mutect2
- TLR4 | c.81G>A p.E27= | Silent (SNP) | VAF 44/445 reads (10%) | catalogued as rs200889734, COSV62923406; called by muse, mutect2
- TNN | c.267C>T p.N89= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs1248382624, COSV99512121; called by muse, mutect2
- TREH | c.1687C>T p.L563= | Silent (SNP) | VAF 10/206 reads (5%) | called by muse, mutect2
- TRPA1 | c.1314C>G p.S438= | Silent (SNP) | VAF 26/536 reads (5%) | catalogued as COSV51565039, COSV51575443; called by muse, mutect2
- TTC37 | c.2940C>T p.A980= | Silent (SNP) | VAF 46/540 reads (9%) | called by muse, mutect2
- UTP14A | c.456G>T p.R152= | Silent (SNP) | VAF 28/402 reads (7%) | called by muse, mutect2
- UTP4 | c.1302A>G p.P434= | Silent (SNP) | VAF 40/528 reads (8%) | catalogued as rs112302105; called by muse, mutect2
- VCAN | c.7524T>C p.N2508= | Silent (SNP) | VAF 20/272 reads (7%) | called by muse, mutect2
- ZFP64 | c.792T>C p.C264= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs751172192; called by muse, mutect2, varscan2
- ZMYM5 | c.1431G>A p.T477= | Silent (SNP) | VAF 34/278 reads (12%) | catalogued as rs1472115336; called by muse, mutect2, varscan2
- ZNF185 | c.888G>T p.L296= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- ZNF311 | c.999C>T p.C333= | Silent (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- ZNF423 | c.348C>A p.S116= (on ENST00000563137 / NM_001379286.1; = p.S108= on NM_015069.4) | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- ZNF454 | c.765G>T p.V255= | Silent (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- ZNF75D | c.636T>A p.S212= | Silent (SNP) | VAF 32/276 reads (12%) | called by muse, mutect2, varscan2
- AAK1 | c.*10143G>C | 3'UTR (SNP) | VAF 14/231 reads (6%) | called by muse, mutect2
- AC008060.1 | n.207G>T | RNA (SNP) | VAF 10/58 reads (17%) | called by muse, varscan2
- AC008619.1 | chr5:170483126 C>T | 3'Flank (SNP) | VAF 11/103 reads (11%) | catalogued as rs1460873520; called by muse, mutect2, varscan2
- AC011487.2 | n.951G>T | RNA (SNP) | VAF 15/252 reads (6%) | called by muse, mutect2
- AC083864.1 | n.491C>A | RNA (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+7677A>T | Intron (SNP) | VAF 62/460 reads (13%) | called by muse, mutect2, varscan2
- ADTRP | c.659-2889C>A | Intron (SNP) | VAF 41/319 reads (13%) | called by muse, mutect2, varscan2
- AIRE | c.880-210G>A | Intron (SNP) | VAF 30/213 reads (14%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821738 C>A | 5'Flank (SNP) | VAF 25/221 reads (11%) | called by muse, mutect2, varscan2
- AL356414.1 | n.463C>T | RNA (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- AUTS2 | c.1933-70T>C | Intron (SNP) | VAF 17/227 reads (7%) | called by muse, mutect2
- BAGE2 | n.253C>G | RNA (SNP) | VAF 47/1114 reads (4%) | called by muse, mutect2
- BLK | c.1030-269C>A | Intron (SNP) | VAF 20/286 reads (7%) | called by muse, mutect2
- C17orf107 | c.*2079del | 3'UTR (DEL) | VAF 38/308 reads (12%) | catalogued as rs35905809; called by mutect2, pindel, varscan2
- CABP1 | c.655-3898C>A | Intron (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- CABP1 | c.655-3766C>A | Intron (SNP) | VAF 31/158 reads (20%) | catalogued as rs766135094; called by muse, mutect2, varscan2
- CCDC61 | c.-36G>T | 5'UTR (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- CD163L1 | c.*4T>C | 3'UTR (SNP) | VAF 53/228 reads (23%) | called by muse, mutect2, varscan2
- CDK18 | c.130+51C>T | Intron (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- CDKL2 | c.1416+4063A>G | Intron (SNP) | VAF 19/182 reads (10%) | catalogued as rs113327297; called by muse, mutect2, varscan2
- CHRNA4 | c.*3319G>T | 3'UTR (SNP) | VAF 42/322 reads (13%) | called by muse, mutect2, varscan2
- COG6 | c.*927G>T | 3'UTR (SNP) | VAF 16/273 reads (6%) | called by muse, mutect2
- COL6A2 | c.2461+2614C>A | Intron (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- COLEC11 | c.130+1731G>A | Intron (SNP) | VAF 21/253 reads (8%) | called by muse, mutect2
- DDC | c.944+2430G>T | Intron (SNP) | VAF 18/238 reads (8%) | catalogued as rs1298899662; called by muse, mutect2
- DHRS4-AS1 | n.3096G>C | RNA (SNP) | VAF 24/380 reads (6%) | called by muse, mutect2
- DNAH11 | c.10897-887C>A | Intron (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- DPF1 | c.676+278G>T | Intron (SNP) | VAF 18/184 reads (10%) | called by muse, mutect2
- DPP6 | c.627+20977G>T | Intron (SNP) | VAF 25/281 reads (9%) | called by muse, mutect2
- ENTPD2 | c.1150-139G>T | Intron (SNP) | VAF 26/343 reads (8%) | catalogued as rs553845490; called by muse, mutect2
- ERBB4 | c.234+25T>A | Intron (SNP) | VAF 20/349 reads (6%) | called by muse, mutect2
- ESPNP | n.355G>T | RNA (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- FAH | c.455+10G>T | Intron (SNP) | VAF 25/426 reads (6%) | called by muse, mutect2
- FAM136A | c.87+41G>T | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- FMO6P | n.1632C>A | RNA (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- FRG1BP | n.507A>T | RNA (SNP) | VAF 28/359 reads (8%) | called by muse, mutect2
- GATA3 | chr10:8051177 G>T | 5'Flank (SNP) | VAF 4/30 reads (13%) | catalogued as rs975957429; called by muse, mutect2
- GPS1 | chr17:82051902 G>T | 5'Flank (SNP) | VAF 3/10 reads (30%) | called by muse, varscan2
- GUCY1B2 | n.1633T>A | RNA (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
65 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 65 other) are not listed here.
